TCGA case TCGA-LA-A7SW — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Candler. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0425cb44-66af-4e25-afcb-cacccc2f1179

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 71 years; Vital status: Dead; Days to death: 408 days (1.1 years).

Diagnoses (5)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 71.5 years (26,116 days); Year of diagnosis: 2013; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 408 days (1.1 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Docetaxel; Days to treatment start: 65 days; Days to treatment end: 65 days.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 243 days; Days to treatment end: 254 days; Treatment dose: 30 Gy; Treatment outcome: Progressive Disease; Number of fractions: 10; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 337 days; Days to treatment end: 350 days; Treatment dose: 30 Gy; Treatment outcome: Progressive Disease; Number of fractions: 10; Treatment anatomic sites: Distant Site.
2. Recurrence of diagnosis 1 (Squamous cell carcinoma, NOS). Age at diagnosis: 72.1 years (26,351 days); Days to diagnosis: 235 days; Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Surgery, NOS to Locoregional Site.
3. Recurrence of diagnosis 1 (Squamous cell carcinoma, NOS). Age at diagnosis: 72.1 years (26,352 days); Days to diagnosis: 236 days; Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Surgery, NOS to Locoregional Site.
4. Metastasis of diagnosis 1 (Squamous cell carcinoma, NOS). Age at diagnosis: 72.2 years (26,353 days); Days to diagnosis: 237 days; Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Surgery, NOS to Distant Site.
5. Recurrence of diagnosis 1 (Squamous cell carcinoma, NOS). Age at diagnosis: 72.4 years (26,427 days); Days to diagnosis: 311 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS to Locoregional Site.

Follow-up (7 entries)
- Day 235 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 235 days; Evidence of recurrence type: Convincing Image Source.
- Day 236 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 236 days; Evidence of recurrence type: Biopsy with Histologic Confirmation.
- Day 237 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 237 days; Evidence of progression type: Convincing Image Source.
- Day 311 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 311 days; Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 408 days (1.1 years); Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Preoperative.
- Follow-up contact recording only the day: day 146.

Other clinical attributes
- DLCO (% of predicted): 41; FEV1/FVC after bronchodilator (%): 77; FEV1/FVC before bronchodilator (%): 78; FEV1 after bronchodilator (% of reference): 72; FEV1 before bronchodilator (% of reference): 69.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 37; Tobacco smoking onset year: 1962; Tobacco smoking quit year: 2012.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-LA-A7SW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 480 mg.
  Slide TCGA-LA-A7SW-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 20; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-LA-A7SW-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-LA-A7SW-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tobacco smoking history indicator: 4; Anatomic organ subdivision: L-Upper; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes.
- Drug treatment 2: Pharmaceutical therapy drug name: Taxotere.
- Radiation treatment 1: Treatment best response: Radiographic Progressive Disease.
- Follow-up form 1: Lost to follow-up: No; New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: No.
- Follow-up form 1, New neoplasm event types: New tumor event type: Locoregional Recurrence.
- Follow-up form 1, Progression determined by list: New tumor event diagnosis evidence: Convincing Imaging.
- Follow-up form 3: Lost to follow-up: No; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: No; New tumor event surgery met: No.
- Follow-up form 3, New neoplasm event types: New tumor event type: Distant Metastasis.
- Follow-up form 4: Lost to follow-up: No; New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 408 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 408 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 235 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-LA-A7SW-01A-11D-A400-01): tumor purity 0.48, ploidy 2.33, whole-genome doublings 1.
